Somatic mutation profile of tumor specimen C3N-04124-01 (aliquot CPT0237970010) from CPTAC case C3N-04124, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 62.7 years (22,895 days).
Specimen C3N-04124-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0a5ce67-ec6f-46aa-93a5-2aa1fb8cbe17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04124-31 (Blood Derived Normal), aliquot CPT0238030002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a411a149-8927-4045-91e1-0496df8b63c9

The open-access MAF lists 319 somatic variants for this specimen: 185 protein-altering or splice-affecting, 82 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 155, Silent 82, Intron 22, Nonsense Mutation 17, RNA 12, 3'UTR 7, Frame Shift Del 7, 5'UTR 4, 5'Flank 4, Splice Site 3, 3'Flank 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.392A>T p.N131I | Missense Mutation (SNP) | VAF 94/327 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1131691037, CM087281, CM159290, COSV52670715, COSV52718021, COSV53252418; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABHD11 | c.812T>C p.V271A | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs781856491; called by muse, mutect2, varscan2
- AFF3 | c.1843G>T p.G615W | Missense Mutation (SNP) | VAF 42/334 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV100418565; called by muse, mutect2, varscan2
- AHNAK2 | c.6643G>C p.G2215R | Missense Mutation (SNP) | VAF 268/586 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs372279497; called by muse, varscan2
- AKR1B10 | c.900C>G p.N300K | Missense Mutation (SNP) | VAF 27/297 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100610155; called by muse, mutect2
- ANKRD12 | c.3526G>A p.G1176R | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs748458767; called by muse, mutect2, varscan2
- AR | c.2499G>A p.M833I | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs1343953915, COSV101019367; called by muse, mutect2, varscan2
- ARID1B | c.5494C>T p.R1832C | Missense Mutation (SNP) | VAF 22/390 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs766931727; ClinVar: uncertain significance; called by muse, mutect2
- ARMC5 | c.2324G>T p.R775L | Missense Mutation (SNP) | VAF 97/318 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV51655615; called by muse, mutect2, varscan2
- AXIN2 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 49/640 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs750274537, COSV100196810; ClinVar: uncertain significance; called by muse, mutect2
- BMP10 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1420667461, COSV99770246; called by muse, mutect2
- C7orf33 | c.100C>A p.R34S | Missense Mutation (SNP) | VAF 118/585 reads (20%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV61022855, COSV61023427; called by muse, mutect2, varscan2
- CACNA1C | c.6098G>A p.R2033Q (on ENST00000399634 / NM_001167625.1; = p.R1962Q on NM_000719.7) | Missense Mutation (SNP) | VAF 32/352 reads (9%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs199776761; ClinVar: uncertain significance; called by muse, mutect2
- CACNA1H | c.6262G>A p.G2088R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.996); catalogued as rs779925007; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CADPS | c.272G>T p.S91I | Missense Mutation (SNP) | VAF 134/411 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as COSV51893372; called by muse, mutect2, varscan2
- CCSER1 | c.2324C>A p.T775K | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.075); catalogued as COSV61427653; called by muse, mutect2, varscan2
- CCT8L2 | c.709A>G p.S237G | Missense Mutation (SNP) | VAF 63/468 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV63463328; called by muse, mutect2, varscan2
- CDC20B | c.311G>C p.G104A | Missense Mutation (SNP) | VAF 100/337 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs370821763; called by muse, mutect2, varscan2
- CFHR3 | c.126C>G p.Y42* | Nonsense Mutation (SNP) | VAF 36/248 reads (15%) | catalogued as COSV66403135; called by muse, mutect2, varscan2
- CNR1 | c.1247A>G p.E416G | Missense Mutation (SNP) | VAF 37/357 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV100759372; called by muse, mutect2, varscan2
- COL16A1 | c.2809G>A p.G937R | Missense Mutation (SNP) | VAF 123/439 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1208853870; called by muse, mutect2, varscan2
- DCAF12L1 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV64422041; called by muse, mutect2, varscan2
- DCC | c.4085del p.P1362Lfs*18 | Frame Shift Del (DEL) | VAF 119/821 reads (14%) | catalogued as COSV71435554; called by mutect2, pindel, varscan2
- EPOR | c.1042G>C p.G348R | Missense Mutation (SNP) | VAF 188/734 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV99710182; called by muse, mutect2, varscan2
- FASN | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 186/1056 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.66); catalogued as rs1412296163; called by muse, mutect2, varscan2
- FLG | c.2353G>T p.E785* | Nonsense Mutation (SNP) | VAF 33/652 reads (5%) | catalogued as rs1271847995; called by muse, mutect2
- FMN2 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 55/267 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs764756141; called by muse, mutect2, varscan2
- GALNT7 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1231639877; called by muse, mutect2, varscan2
- GRIK3 | c.550G>T p.G184W | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66147135; called by muse, mutect2
- GRIN2A | c.2567G>A p.R856Q | Missense Mutation (SNP) | VAF 162/539 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.34); catalogued as rs368881818; called by muse, mutect2, varscan2
- HACE1 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs1353683792; called by muse, mutect2
- HCN1 | c.2296G>T p.E766* | Nonsense Mutation (SNP) | VAF 124/319 reads (39%) | catalogued as COSV57499129; called by muse, mutect2, varscan2
- IMPG2 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 42/430 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs777952275; called by muse, mutect2
- INSC | c.1633G>T p.G545W | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs749397195; called by muse, mutect2
- ITSN1 | c.329C>G p.S110C | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV66084088; called by muse, mutect2
- KCNH7 | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as rs1229855251, COSV100146782, COSV59796250; called by muse, mutect2, varscan2
- KIAA1549 | c.1582C>T p.L528F | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as rs776027490; called by muse, mutect2, varscan2
- LIPT1 | c.228G>T p.R76S | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1294380580; called by muse, mutect2, varscan2
- MAB21L1 | c.903C>A p.N301K | Missense Mutation (SNP) | VAF 71/225 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.168); catalogued as COSV59765829; called by muse, mutect2, varscan2
- MAGEE1 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1556839575, COSV63912819; called by muse, mutect2, varscan2
- MAGEL2 | c.200C>A p.A67D | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious, low confidence (0); catalogued as rs535440723; called by muse, mutect2
- MAP2K3 | c.607C>A p.H203N (on ENST00000342679 / NM_145109.3; = p.H174N on NM_002756.4) | Missense Mutation (SNP) | VAF 70/596 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.324); catalogued as COSV100383338; called by muse, mutect2, varscan2
- MAPK4 | c.1480G>T p.A494S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.026); catalogued as COSV68543109; called by muse, mutect2, varscan2
- MED12L | c.6272G>A p.G2091D | Missense Mutation (SNP) | VAF 75/802 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs375930902; called by muse, mutect2
- MYH15 | c.4252del p.V1418Wfs*107 | Frame Shift Del (DEL) | VAF 58/204 reads (28%) | catalogued as COSV56318499; called by mutect2, pindel
- MYH7B | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 50/594 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs201578499, COSV53416647; called by muse, mutect2
- NAV3 | c.3592G>T p.D1198Y | Missense Mutation (SNP) | VAF 103/374 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57059835; called by muse, mutect2, varscan2
- NLRP10 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 53/274 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1564877699; called by muse, mutect2, varscan2
- NLRP11 | c.2548C>A p.Q850K | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.053); catalogued as COSV64085864, COSV64088751; called by muse, mutect2
- NNAT | c.196C>T p.R66W (on ENST00000649309 / NM_001322802.2; = p.T67= on NM_005386.4) | Missense Mutation (SNP) | VAF 59/289 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs756916248, COSV50351747; called by muse, mutect2, varscan2
- OPRL1 | c.776G>T p.R259L | Missense Mutation (SNP) | VAF 118/736 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100401994; called by muse, mutect2, varscan2
- OR2H2 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 69/213 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV99054577; called by muse, mutect2, varscan2
- OR52N1 | c.503T>C p.L168P | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1287850672; called by muse, mutect2
- PCLO | c.5658G>C p.L1886F | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100439659; called by muse, mutect2, varscan2
- PPP2R5E | c.481T>G p.F161V | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.321); catalogued as rs1313412531; called by muse, mutect2
- PRKG2 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 27/73 reads (37%) | catalogued as COSV52328136; called by muse, mutect2, varscan2
- PTPRQ | c.1169G>T p.R390L (on ENST00000616559; = p.R348L on NM_001145026.2) | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs775296221, COSV57050741; called by muse, mutect2
- RARRES1 | c.672+1G>A p.X224_splice (on ENST00000237696 / NM_206963.2; = p.V225I on NM_002888.3) | Splice Site (SNP) | VAF 123/185 reads (66%) | catalogued as rs879094429; called by muse, mutect2, varscan2
- SCAF1 | c.2255G>T p.R752L | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.253); catalogued as COSV100862078; called by muse, mutect2
- SLIT3 | c.1380C>A p.S460R | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100265173; called by muse, mutect2, varscan2
- SPATA4 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99708855; called by muse, mutect2, varscan2
- STARD7 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.31); catalogued as COSV61525174; called by muse, mutect2
- TANC2 | c.4864G>A p.V1622I | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.796); catalogued as rs745873428, COSV67342522; called by muse, mutect2, varscan2
- TBC1D31 | c.329G>A p.C110Y | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757389232; called by muse, mutect2
- TDRD9 | c.3098C>T p.A1033V | Missense Mutation (SNP) | VAF 124/440 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV59154847; called by muse, mutect2, varscan2
- TLR7 | c.1078A>G p.M360V | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs201181342; called by muse, mutect2, varscan2
- TMEM63B | c.2237C>T p.T746M | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs758681511; called by muse, mutect2
- TNNI1 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 72/307 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.238); catalogued as rs201090247; called by muse, mutect2, varscan2
- TTN | c.34166G>T p.R11389L (on ENST00000591111; = p.R10462L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/190 reads (12%) | PolyPhen benign (0.066); catalogued as COSV100623372, COSV59952868; called by muse, mutect2, varscan2
- ZNF516 | c.2875G>T p.G959W | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101487292; called by muse, mutect2, varscan2
- ZNF546 | c.1861C>A p.Q621K | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0.19); catalogued as COSV61257326; called by muse, mutect2, varscan2
- ABCG8 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 194/688 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC004922.1 | c.873G>C p.Q291H | Missense Mutation (SNP) | VAF 141/747 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- ACP6 | c.480-3C>T | Splice Region (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- ADAMTS6 | c.2170A>G p.N724D | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- ADGRL3 | c.1445A>T p.H482L (on ENST00000506720 / NM_001322402.2; = p.H414L on NM_015236.6) | Missense Mutation (SNP) | VAF 69/272 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALMS1 | c.2480A>G p.D827G | Missense Mutation (SNP) | VAF 48/344 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- AP002512.3 | c.607C>A p.Q203K | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- ASH1L | c.2411T>G p.F804C | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- CACNA1A | c.5808G>A p.W1936* | Nonsense Mutation (SNP) | VAF 47/384 reads (12%) | called by muse, mutect2, varscan2
- CCDC178 | c.638T>C p.L213P | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2
- CD276 | c.1604G>T p.*535Lext*2 (on ENST00000318443 / NM_001024736.2; = p.*317Lext*2 on NM_025240.2 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 33/145 reads (23%) | called by muse, mutect2, varscan2
- CDK9 | c.813G>C p.Q271H | Missense Mutation (SNP) | VAF 44/297 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CEP164 | c.4008G>T p.W1336C | Missense Mutation (SNP) | VAF 72/336 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CFH | c.610A>T p.K204* | Nonsense Mutation (SNP) | VAF 36/207 reads (17%) | called by muse, mutect2, varscan2
- CLIP4 | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 69/342 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLMN | c.2709-2A>T p.X903_splice | Splice Site (SNP) | VAF 45/152 reads (30%) | called by muse, mutect2, varscan2
- CLTC | c.879C>G p.I293M | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2
- COPS6 | c.421C>A p.Q141K | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CSMD1 | c.7316T>A p.L2439Q (on ENST00000520002; = p.L2438Q on NM_033225.6) | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.399); called by mutect2, varscan2
- CYP11B1 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 32/767 reads (4%) | called by muse, mutect2
- DCAF12L2 | c.563G>C p.G188A | Missense Mutation (SNP) | VAF 83/293 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND1A | c.300_302+13del p.X100_splice | Splice Site (DEL) | VAF 50/114 reads (44%) | called by mutect2, pindel
- DLX2 | c.797del p.G266Afs*57 | Frame Shift Del (DEL) | VAF 70/557 reads (13%) | called by mutect2, pindel, varscan2
- DOCK2 | c.3773G>T p.C1258F | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- DTX1 | c.1785C>G p.Y595* | Nonsense Mutation (SNP) | VAF 19/472 reads (4%) | called by muse, mutect2
- DYNC1I1 | c.37C>A p.R13S | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFL1 | c.3251A>G p.E1084G | Missense Mutation (SNP) | VAF 36/472 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2
- ERVV-1 | c.1118C>A p.S373Y | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ETV5 | c.1045G>T p.V349F | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2
- FAM133A | c.31A>C p.M11L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FAM47C | c.1382G>T p.S461I | Missense Mutation (SNP) | VAF 92/295 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- FBXO32 | c.83A>G p.E28G | Missense Mutation (SNP) | VAF 15/462 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2
- FGGY | c.530G>C p.W177S | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FLG2 | c.5815C>A p.Q1939K | Missense Mutation (SNP) | VAF 92/604 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- FSIP2 | c.4278G>T p.E1426D | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, mutect2
- GLI2 | c.4621G>T p.A1541S (on ENST00000361492 / NM_001374353.1; = p.A1558S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- GOLGA6L2 | c.964A>T p.R322W | Missense Mutation (SNP) | VAF 42/296 reads (14%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- GPR158 | c.3253G>T p.E1085* | Nonsense Mutation (SNP) | VAF 46/512 reads (9%) | called by muse, mutect2
- HCN1 | c.550A>G p.T184A | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HECW1 | c.2308C>T p.Q770* | Nonsense Mutation (SNP) | VAF 38/410 reads (9%) | called by muse, mutect2
- HERC2 | c.11218C>T p.R3740* | Nonsense Mutation (SNP) | VAF 13/447 reads (3%) | called by muse, mutect2
- HK2 | c.1104del p.C368Wfs*89 | Frame Shift Del (DEL) | VAF 70/683 reads (10%) | called by mutect2, pindel, varscan2
- HSD3B2 | c.47A>G p.Q16R | Missense Mutation (SNP) | VAF 110/453 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HTR1E | c.956_962del p.Y319Cfs*9 | Frame Shift Del (DEL) | VAF 54/168 reads (32%) | called by mutect2, pindel, varscan2
- IGLV1-40 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 51/478 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- ITPRID1 | c.1591G>A p.G531R | Missense Mutation (SNP) | VAF 103/537 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- KCNN3 | c.1531G>T p.G511C (on ENST00000618040 / NM_001204087.1; = p.G496C on NM_002249.6) | Missense Mutation (SNP) | VAF 105/613 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KLHL4 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.357); called by muse, varscan2
- KLHL6 | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 166/252 reads (66%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); called by muse, mutect2
- KMT2E | c.2692C>T p.P898S | Missense Mutation (SNP) | VAF 73/450 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KRTAP4-12 | c.209G>T p.C70F | Missense Mutation (SNP) | VAF 34/648 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- LOXL1 | c.45G>C p.W15C | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- LRP1B | c.12292G>A p.V4098I | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAGEB2 | c.28C>A p.R10S | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MANEA | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 18/251 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- MANSC1 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MAP3K19 | c.1602T>A p.H534Q | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MAP3K20 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.109); called by muse, mutect2
- MCM4 | c.762A>T p.L254F | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MED12L | c.2264T>A p.L755Q | Missense Mutation (SNP) | VAF 16/484 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MGAM | c.4877C>G p.A1626G | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2
- MINAR1 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- MUC17 | c.9014G>C p.S3005T | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- MYBPHL | c.59C>A p.A20D | Missense Mutation (SNP) | VAF 89/320 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.043); called by muse, varscan2
- MYH15 | c.4051G>A p.D1351N | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NOVA2 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 146/505 reads (29%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- NOX1 | c.1277A>G p.H426R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR13G1 | c.413G>A p.C138Y | Missense Mutation (SNP) | VAF 51/362 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- OR1L6 | c.497C>A p.P166H (on ENST00000373684; = p.P130H on NM_001004453.2) | Missense Mutation (SNP) | VAF 49/366 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- OR5A2 | c.82C>A p.L28I | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); called by muse, mutect2
- PAK5 | c.448A>T p.S150C | Missense Mutation (SNP) | VAF 18/491 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.241); called by muse, mutect2
- PARP10 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PCLO | c.7885G>C p.V2629L | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- PEX11A | c.552A>T p.L184F | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- POLR2A | c.3455A>C p.E1152A | Missense Mutation (SNP) | VAF 74/241 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.412); called by muse, varscan2
- POM121 | c.3668C>G p.S1223* (on ENST00000434423; = p.S958* on NM_172020.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 35/271 reads (13%) | called by muse, mutect2, varscan2
- PPARGC1A | c.759C>T p.A253= | Splice Region (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2
- PPP4R3C | c.263C>G p.A88G | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PRCC | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 77/433 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PRNP | c.269del p.G90Vfs*20 | Frame Shift Del (DEL) | VAF 121/568 reads (21%) | called by mutect2, pindel, varscan2
- PRRC2C | c.1544G>T p.R515L (on ENST00000367742; = p.R513L on NM_015172.4) | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- RILPL1 | c.150C>G p.I50M | Missense Mutation (SNP) | VAF 90/851 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- RNF133 | c.840G>C p.K280N | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RTL9 | c.1825C>G p.L609V | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SCFD1 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.364); called by muse, mutect2
- SEL1L3 | c.455G>T p.S152I | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- SEMA3D | c.868G>T p.V290L | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.022); called by muse, mutect2
- SGCD | c.743del p.G248Dfs*36 (on ENST00000435422 / NM_001128209.2; = p.G249Dfs*36 on NM_000337.5) | Frame Shift Del (DEL) | VAF 56/246 reads (23%) | called by mutect2, pindel, varscan2
- SH2D3A | c.1562G>T p.R521L | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SHROOM3 | c.1966G>T p.G656C | Missense Mutation (SNP) | VAF 100/345 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SLC10A2 | c.104G>C p.S35T | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLCO1A2 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNX24 | c.197G>A p.W66* | Nonsense Mutation (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- SPATA48 | c.1308A>G p.I436M | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- STX19 | c.107A>C p.Q36P | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- SYNE1 | c.4697A>T p.Q1566L (on ENST00000367255 / NM_182961.4; = p.Q1573L on NM_033071.3) | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TBC1D3F | c.1472C>A p.P491H | Missense Mutation (SNP) | VAF 83/825 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- TFEC | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- THAP7 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 76/374 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLL2 | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBA7 | c.2627G>T p.R876L | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2
- UBE3C | c.3112G>T p.G1038* | Nonsense Mutation (SNP) | VAF 55/244 reads (23%) | called by muse, mutect2, varscan2
- UGGT1 | c.1419G>T p.W473C | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- UNC5C | c.2063G>C p.G688A | Missense Mutation (SNP) | VAF 18/488 reads (4%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); called by muse, mutect2
- UNC5CL | c.1117G>T p.D373Y | Missense Mutation (SNP) | VAF 68/317 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by mutect2, varscan2
- UTRN | c.2572G>T p.A858S | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2
- VPS33A | c.1123A>G p.T375A | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- XPOT | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- XRRA1 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZIC1 | c.38G>C p.G13A | Missense Mutation (SNP) | VAF 308/440 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ZMYND8 | c.2502G>T p.M834I | Missense Mutation (SNP) | VAF 63/369 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ZNF208 | c.498G>T p.R166S | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- ZNF483 | c.394C>A p.Q132K | Missense Mutation (SNP) | VAF 69/373 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ZNF781 | c.359A>T p.K120M | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- A4GALT | c.396T>G p.L132= | Silent (SNP) | VAF 53/382 reads (14%) | called by muse, mutect2, varscan2
- AATF | c.1293A>C p.P431= | Silent (SNP) | VAF 31/104 reads (30%) | called by muse, mutect2, varscan2
- AC244197.3 | c.531A>T p.S177= | Silent (SNP) | VAF 50/149 reads (34%) | called by muse, mutect2, varscan2
- ADGRL3 | c.4071T>C p.R1357= (on ENST00000506720 / NM_001322402.2; = p.R1246= on NM_015236.6) | Silent (SNP) | VAF 115/440 reads (26%) | catalogued as rs763373770; called by muse, mutect2, varscan2
- ALKAL1 | c.270C>T p.C90= | Silent (SNP) | VAF 14/348 reads (4%) | called by muse, mutect2
- APBA1 | c.717C>T p.D239= | Silent (SNP) | VAF 72/268 reads (27%) | catalogued as rs773533052; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1401A>G p.L467= | Silent (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- ASB15 | c.564C>A p.G188= | Silent (SNP) | VAF 110/595 reads (18%) | called by muse, mutect2, varscan2
- C10orf71 | c.3177C>T p.P1059= | Silent (SNP) | VAF 32/182 reads (18%) | called by muse, mutect2, varscan2
- CA9 | c.652C>A p.R218= | Silent (SNP) | VAF 1107/1477 reads (75%) | catalogued as rs1331881437; called by muse, mutect2, varscan2
- CCT6A | c.1128C>T p.I376= | Silent (SNP) | VAF 11/214 reads (5%) | called by muse, mutect2
- COL9A1 | c.1791T>C p.P597= | Silent (SNP) | VAF 173/718 reads (24%) | called by muse, mutect2, varscan2
- COPG1 | c.585C>T p.H195= | Silent (SNP) | VAF 28/244 reads (11%) | catalogued as rs755610468; called by muse, mutect2
- CRYBG1 | c.861G>A p.Q287= | Silent (SNP) | VAF 45/159 reads (28%) | catalogued as rs1267331415; called by muse, mutect2, varscan2
- DSCC1 | c.1113C>G p.L371= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV100558409; called by muse, mutect2, varscan2
- DUSP8 | c.1206C>T p.Y402= | Silent (SNP) | VAF 15/261 reads (6%) | catalogued as rs910811917; called by muse, mutect2
- FAM78A | c.585C>T p.A195= | Silent (SNP) | VAF 12/258 reads (5%) | catalogued as rs1444913095; called by muse, mutect2
- FLNA | c.7557C>T p.P2519= (on ENST00000369850 / NM_001110556.2; = p.P2511= on NM_001456.3) | Silent (SNP) | VAF 89/255 reads (35%) | called by muse, mutect2, varscan2
- FLRT2 | c.1389G>C p.G463= | Silent (SNP) | VAF 54/169 reads (32%) | catalogued as rs373146061; called by muse, mutect2, varscan2
- FRRS1 | c.417C>T p.H139= | Silent (SNP) | VAF 13/193 reads (7%) | called by muse, mutect2
- FSIP2 | c.4047T>C p.D1349= | Silent (SNP) | VAF 31/111 reads (28%) | called by muse, mutect2, varscan2
- GRM5 | c.2475C>A p.I825= | Silent (SNP) | VAF 45/256 reads (18%) | called by muse, mutect2, varscan2
- HR | c.957G>A p.P319= | Silent (SNP) | VAF 37/292 reads (13%) | catalogued as rs1287589631, COSV57192317; called by muse, mutect2, varscan2
- HRH1 | c.516C>A p.T172= | Silent (SNP) | VAF 33/312 reads (11%) | called by muse, mutect2
- IFT172 | c.3195C>T p.Y1065= | Silent (SNP) | VAF 106/398 reads (27%) | catalogued as rs1292961865; called by muse, mutect2, varscan2
- IGSF10 | c.6891C>A p.T2297= | Silent (SNP) | VAF 36/888 reads (4%) | called by muse, mutect2
- KLHL4 | c.150C>A p.G50= | Silent (SNP) | VAF 50/176 reads (28%) | called by muse, varscan2
- LRRC14B | c.399C>A p.G133= | Silent (SNP) | VAF 126/357 reads (35%) | catalogued as rs1319928619; called by muse, mutect2, varscan2
- MAGEL2 | c.1182C>A p.V394= | Silent (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- MANSC1 | c.717G>T p.S239= | Silent (SNP) | VAF 33/222 reads (15%) | catalogued as COSV101115938; called by muse, mutect2, varscan2
- MARCHF7 | c.1947G>A p.L649= | Silent (SNP) | VAF 30/202 reads (15%) | called by muse, mutect2, varscan2
- MASP1 | c.1698C>T p.A566= | Silent (SNP) | VAF 49/391 reads (13%) | catalogued as rs908912783; called by muse, mutect2, varscan2
- MMP16 | c.858C>A p.I286= | Silent (SNP) | VAF 34/150 reads (23%) | called by muse, mutect2, varscan2
- MRGPRX3 | c.180T>A p.A60= | Silent (SNP) | VAF 36/201 reads (18%) | called by muse, mutect2, varscan2
- MYO3A | c.684T>A p.P228= | Silent (SNP) | VAF 15/373 reads (4%) | called by muse, mutect2
- NACAD | c.4329C>A p.I1443= | Silent (SNP) | VAF 97/504 reads (19%) | called by muse, mutect2, varscan2
- NOTCH4 | c.4638C>T p.P1546= | Silent (SNP) | VAF 22/292 reads (8%) | called by muse, mutect2
- OR10R2 | c.213G>T p.L71= | Silent (SNP) | VAF 43/251 reads (17%) | catalogued as COSV100936764; called by muse, mutect2, varscan2
- OR11L1 | c.852G>T p.L284= | Silent (SNP) | VAF 32/298 reads (11%) | called by muse, mutect2, varscan2
- OR9A2 | c.282T>C p.S94= | Silent (SNP) | VAF 52/258 reads (20%) | catalogued as rs1386058750; called by muse, mutect2, varscan2
- PCNX3 | c.5313C>G p.S1771= | Silent (SNP) | VAF 122/644 reads (19%) | called by muse, mutect2, varscan2
- PDILT | c.1200C>T p.V400= | Silent (SNP) | VAF 57/176 reads (32%) | catalogued as rs758522370; called by muse, mutect2, varscan2
- PGM1 | c.138C>A p.T46= | Silent (SNP) | VAF 206/628 reads (33%) | catalogued as rs767357022; called by muse, mutect2, varscan2
- PITPNC1 | c.489G>A p.K163= | Silent (SNP) | VAF 11/169 reads (7%) | catalogued as rs1163767879; called by muse, mutect2
- PLCXD3 | c.681G>A p.Q227= | Silent (SNP) | VAF 14/432 reads (3%) | called by muse, mutect2
- PLXND1 | c.1099C>A p.R367= | Silent (SNP) | VAF 283/727 reads (39%) | called by muse, mutect2, varscan2
- POM121L2 | c.129C>T p.F43= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- PPL | c.789G>A p.L263= | Silent (SNP) | VAF 82/285 reads (29%) | called by muse, mutect2, varscan2
- PPP1R3C | c.57C>T p.V19= | Silent (SNP) | VAF 154/531 reads (29%) | catalogued as rs1345263071; called by muse, mutect2, varscan2
- PRICKLE2 | c.1464G>T p.G488= (on ENST00000295902; = p.G432= on NM_198859.4) | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as rs760982351; called by muse, mutect2, varscan2
- PROSER1 | c.2544T>A p.A848= | Silent (SNP) | VAF 33/95 reads (35%) | called by muse, mutect2, varscan2
- RIPOR1 | c.1182C>T p.L394= (on ENST00000379312 / NM_001193522.2; = p.L390= on NM_024519.4) | Silent (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- RPS6KA1 | c.597C>T p.G199= | Silent (SNP) | VAF 26/144 reads (18%) | called by muse, mutect2, varscan2
- SGIP1 | c.1218A>T p.G406= | Silent (SNP) | VAF 51/209 reads (24%) | called by muse, mutect2, varscan2
- SHOX | c.702G>T p.A234= | Silent (SNP) | VAF 141/723 reads (20%) | called by muse, mutect2, varscan2
- SLC2A13 | c.861C>A p.T287= | Silent (SNP) | VAF 28/385 reads (7%) | called by muse, mutect2
- SORBS1 | c.3294G>T p.G1098= | Silent (SNP) | VAF 14/155 reads (9%) | called by muse, mutect2
- SPTBN4 | c.5676G>A p.R1892= | Silent (SNP) | VAF 47/221 reads (21%) | catalogued as rs1480124801; called by muse, mutect2
- SRPX | c.852C>A p.A284= | Silent (SNP) | VAF 56/191 reads (29%) | called by muse, mutect2, varscan2
- ST8SIA2 | c.699C>T p.L233= | Silent (SNP) | VAF 74/698 reads (11%) | called by muse, mutect2
- STAT5B | c.2097C>T p.Y699= | Silent (SNP) | VAF 58/724 reads (8%) | catalogued as rs369507540; ClinVar: likely benign; called by muse, mutect2
- STK36 | c.1662G>T p.L554= | Silent (SNP) | VAF 74/225 reads (33%) | called by muse, mutect2, varscan2
- TENM4 | c.5610G>T p.R1870= | Silent (SNP) | VAF 88/524 reads (17%) | catalogued as rs753060104; called by muse, mutect2, varscan2
- TGM2 | c.1596C>T p.L532= | Silent (SNP) | VAF 56/212 reads (26%) | called by muse, mutect2, varscan2
- TMEM132C | c.762A>G p.P254= | Silent (SNP) | VAF 17/162 reads (10%) | called by muse, mutect2, varscan2
- TMEM232 | c.202T>C p.L68= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1222750309; called by muse, mutect2, varscan2
- TNRC18 | c.4902C>G p.L1634= | Silent (SNP) | VAF 66/319 reads (21%) | catalogued as rs764604188, COSV68163751; called by muse, mutect2, varscan2
- TRAPPC12 | c.330C>T p.P110= | Silent (SNP) | VAF 13/315 reads (4%) | catalogued as rs1176910723; called by muse, mutect2
- TRIM27 | c.1098C>T p.F366= | Silent (SNP) | VAF 34/251 reads (14%) | catalogued as rs1252217990, COSV65874203; called by muse, mutect2, varscan2
- TRIM48 | c.612T>A p.P204= | Silent (SNP) | VAF 133/367 reads (36%) | called by muse, mutect2, varscan2
- TRPA1 | c.1158T>A p.P386= | Silent (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- TRPV6 | c.1620C>T p.V540= | Silent (SNP) | VAF 15/490 reads (3%) | called by muse, mutect2
- TUBB4B | c.576C>A p.L192= | Silent (SNP) | VAF 194/470 reads (41%) | called by muse, mutect2, varscan2
- TUBG2 | c.777G>A p.S259= | Silent (SNP) | VAF 36/394 reads (9%) | catalogued as rs141008194, COSV52217788; called by muse, mutect2
- TUBGCP2 | c.1653G>T p.L551= | Silent (SNP) | VAF 114/345 reads (33%) | called by muse, mutect2, varscan2
- TWIST1 | c.402C>A p.I134= | Silent (SNP) | VAF 44/498 reads (9%) | catalogued as CM970036; called by muse, mutect2
- UBA7 | c.2625A>C p.P875= | Silent (SNP) | VAF 66/262 reads (25%) | called by muse, mutect2
- UGT1A5 | c.417G>A p.R139= | Silent (SNP) | VAF 97/582 reads (17%) | called by muse, mutect2, varscan2
- USE1 | c.255G>A p.L85= | Silent (SNP) | VAF 30/306 reads (10%) | called by muse, mutect2
- USH2A | c.9906C>T p.N3302= | Silent (SNP) | VAF 137/617 reads (22%) | catalogued as rs757439664; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZC3H18 | c.1311G>A p.E437= | Silent (SNP) | VAF 133/507 reads (26%) | called by muse, mutect2, varscan2
- ZNF407 | c.5346C>T p.T1782= | Silent (SNP) | VAF 21/119 reads (18%) | called by muse, mutect2, varscan2
- AC244258.1 | n.650G>T | RNA (SNP) | VAF 21/272 reads (8%) | called by muse, mutect2
- ADGRD1 | c.1027-383G>T | Intron (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- AGA | c.*766G>A | 3'UTR (SNP) | VAF 32/462 reads (7%) | catalogued as rs1367080305; called by muse, mutect2
- ALK | c.*32G>T | 3'UTR (SNP) | VAF 55/528 reads (10%) | called by muse, mutect2, varscan2
- BRCA1 | c.*315C>G | 3'UTR (SNP) | VAF 12/167 reads (7%) | called by muse, mutect2
- BSG | c.416-462G>T | Intron (SNP) | VAF 77/343 reads (22%) | called by muse, mutect2, varscan2
- C11orf40 | n.254G>A | RNA (SNP) | VAF 42/253 reads (17%) | called by muse, mutect2, varscan2
- C8orf34-AS1 | n.466A>G | RNA (SNP) | VAF 47/286 reads (16%) | called by muse, mutect2, varscan2
- C8orf87 | n.163C>G | RNA (SNP) | VAF 20/191 reads (10%) | called by muse, mutect2
- CEP164 | c.4096+135dup | Intron (INS) | VAF 15/94 reads (16%) | called by mutect2, pindel, varscan2
- CLEC2D | c.462-877G>A | Intron (SNP) | VAF 11/128 reads (9%) | called by muse, mutect2
- CLEC2D | c.462-876C>A | Intron (SNP) | VAF 11/124 reads (9%) | called by muse, mutect2
- COA1 | c.15+55G>A | Intron (SNP) | VAF 9/252 reads (4%) | called by muse, mutect2
- COL6A2 | c.2461+2643G>A | Intron (SNP) | VAF 61/342 reads (18%) | catalogued as rs748960649; ClinVar: likely benign; called by muse, mutect2, varscan2
- DLGAP1 | c.1592-14767G>T | Intron (SNP) | VAF 70/453 reads (15%) | called by muse, mutect2, varscan2
- EYS | c.-31A>C | 5'UTR (SNP) | VAF 16/168 reads (10%) | catalogued as rs899777314; called by muse, mutect2
- FAM90A27P | n.1145T>A | RNA (SNP) | VAF 15/358 reads (4%) | called by muse, mutect2
- FAM90A27P | n.1146C>A | RNA (SNP) | VAF 15/360 reads (4%) | called by muse, mutect2
- FOXR1 | c.612-220A>C | Intron (SNP) | VAF 39/423 reads (9%) | called by muse, mutect2
- HGS | chr17:81684004 del G | 5'Flank (DEL) | VAF 34/190 reads (18%) | called by mutect2, varscan2
- HLA-F | chr6:29726940 T>A | 3'Flank (SNP) | VAF 11/288 reads (4%) | catalogued as rs1254287782, COSV99465955; called by muse, mutect2
- INVS | c.*50G>C | 3'UTR (SNP) | VAF 23/177 reads (13%) | called by muse, mutect2, varscan2
- LENG8 | c.*2631A>C | 3'UTR (SNP) | VAF 12/256 reads (5%) | called by muse, mutect2
- LINC00574 | n.214G>T | RNA (SNP) | VAF 38/133 reads (29%) | catalogued as rs1266775508; called by muse, mutect2, varscan2
- LINC01664 | n.878del | RNA (DEL) | VAF 44/222 reads (20%) | called by mutect2, pindel, varscan2
- LINC02448 | n.448C>T | RNA (SNP) | VAF 16/129 reads (12%) | called by muse, mutect2, varscan2
- MGAM | c.4619-10083A>G | Intron (SNP) | VAF 77/324 reads (24%) | called by muse, mutect2, varscan2
- MIF | chr22:23895504 C>A | 3'Flank (SNP) | VAF 13/119 reads (11%) | called by muse, mutect2, varscan2
- MOCS1 | c.*1036G>A | 3'UTR (SNP) | VAF 26/542 reads (5%) | called by muse, mutect2
- MRPL21 | c.553+53G>A | Intron (SNP) | VAF 40/460 reads (9%) | catalogued as rs754783689; called by muse, mutect2
- MYO9A | c.5142+625G>C | Intron (SNP) | VAF 64/509 reads (13%) | catalogued as rs1480426197; called by muse, mutect2, varscan2
- NAXD | chr13:110615608 C>A | 5'Flank (SNP) | VAF 29/102 reads (28%) | called by muse, mutect2, varscan2
- OPRM1 | c.1164+2766G>T | Intron (SNP) | VAF 64/211 reads (30%) | catalogued as rs922195487; called by muse, mutect2, varscan2
- PACRG | c.613+89849G>A | Intron (SNP) | VAF 67/223 reads (30%) | called by muse, mutect2, varscan2
- PLIN1 | c.*21G>T | 3'UTR (SNP) | VAF 85/331 reads (26%) | called by muse, mutect2, varscan2
- PODXL | c.1023+124C>T | Intron (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- PPP1R1A | chr12:54577498 G>A | 3'Flank (SNP) | VAF 15/59 reads (25%) | catalogued as rs1243211119; called by muse, mutect2, varscan2
- PTPRD | c.541+149A>T | Intron (SNP) | VAF 41/101 reads (41%) | called by muse, mutect2, varscan2
- RHAG | c.-4A>G | 5'UTR (SNP) | VAF 80/412 reads (19%) | called by muse, mutect2, varscan2
- RN7SL759P | chr15:20568426 G>C | 5'Flank (SNP) | VAF 80/338 reads (24%) | called by muse, mutect2, varscan2
- SDHAP2 | n.1038C>T | RNA (SNP) | VAF 56/420 reads (13%) | catalogued as rs550009355; called by mutect2, varscan2
- SND1 | c.-44C>G | 5'UTR (SNP) | VAF 110/437 reads (25%) | called by muse, mutect2, varscan2
- SNORD116-5 | n.54G>A | RNA (SNP) | VAF 44/449 reads (10%) | called by muse, mutect2, varscan2
- SUMO2P21 | n.146A>T | RNA (SNP) | VAF 126/378 reads (33%) | called by muse, mutect2, varscan2
- TCF7L2 | c.553-11351dup | Intron (INS) | VAF 56/165 reads (34%) | catalogued as rs896259582; called by mutect2, varscan2
- TMC8 | c.298+125C>T | Intron (SNP) | VAF 13/126 reads (10%) | catalogued as rs1461042342; called by muse, mutect2
- TMEM67 | c.407-834C>A | Intron (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2, varscan2
- TSC2 | c.5161-11T>G | Intron (SNP) | VAF 126/400 reads (32%) | catalogued as rs1228931130; called by muse, mutect2, varscan2
- ZFAT | c.2888-138C>T | Intron (SNP) | VAF 16/164 reads (10%) | catalogued as rs1405799779, COSV64737558; called by muse, mutect2
- ZNF252P | n.245+4553A>T | Intron (SNP) | VAF 38/229 reads (17%) | catalogued as rs545662175; called by muse, mutect2, varscan2
- ZNF516 | chr18:76496356 G>A | 5'Flank (SNP) | VAF 84/522 reads (16%) | called by muse, mutect2, varscan2
- ZNF727 | c.-35A>C | 5'UTR (SNP) | VAF 72/417 reads (17%) | called by muse, mutect2, varscan2
